Gene-level copy-number profile of tumor specimen TCGA-DC-6157-01A from TCGA case TCGA-DC-6157, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 48.8 years (17,807 days).
Specimen TCGA-DC-6157-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.e29ca322-0e5d-4b20-954e-7d97868ebadf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DC-6157-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13e209d4-391c-4cc9-89cd-0186ca90670f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 881; copy number 2: 10,506; copy number 3: 25,770; copy number 4: 16,312; copy number 5: 5,239; copy number 7: 32; copy number 8: 453; copy number 9: 71; copy number 11: 220; copy number 12: 132; copy number 15: 112; copy number 16: 92.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DC-6157-01A-11D-1656-01): tumor purity 0.5, ploidy 6.25, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,112 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:9,505,180–50,153,637, 897 genes, copy number 7–16 (within-gene range 5–16) (broad region; genes not listed).
- chr20:57,561,080–64,313,132, 215 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 881. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
